Somatic mutation profile of tumor specimen MMRF_1713_1_BM_CD138pos (aliquot MMRF_1713_1_BM_CD138pos_T1_KBS5U_L04817) from MMRF case MMRF_1713, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.1 years (21,943 days).
Specimen MMRF_1713_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 317d8cc2-c145-424a-9ca8-0202cd842ffb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1713_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1713_1_PB_Whole_C3_KBS5U_L04829; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b18464d8-8eb5-47e2-9187-ebc24cda3585

The open-access MAF lists 77 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 16, Silent 13, Intron 7, 3'Flank 3, 5'UTR 3, RNA 3, 5'Flank 3, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 42/56 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1471A>G p.S491G (on ENST00000399959; = p.S492G on NM_001356.5) | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV67864750; called by muse, mutect2, varscan2
- HSD17B1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1375827629; called by muse, mutect2, varscan2
- IGSF3 | c.1393C>T p.R465W (on ENST00000369486 / NM_001007237.3; = p.R485W on NM_001542.4) | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769362307; called by muse, mutect2, varscan2
- NAALADL1 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as rs1446369297; called by muse, mutect2, varscan2
- NNMT | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs576476423, COSV55474852; called by muse, mutect2
- NR2E3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1205711731, COSV58907651; called by muse, mutect2
- PLXND1 | c.5374G>A p.D1792N | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765136044; called by muse, mutect2, varscan2
- POLR1H | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 155/386 reads (40%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs1418135029, COSV60139041; called by muse, mutect2, varscan2
- SYNE1 | c.2807G>A p.R936Q (on ENST00000367255 / NM_182961.4; = p.R943Q on NM_033071.3) | Missense Mutation (SNP) | VAF 73/82 reads (89%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as rs537794828; called by muse, mutect2, varscan2
- ZBTB20 | c.1667C>T p.A556V (on ENST00000474710 / NM_001164342.2; = p.A483V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1323958910, COSV61862518; called by muse, mutect2, varscan2
- AGTPBP1 | c.2556T>G p.Y852* (on ENST00000357081 / NM_001330701.2; = p.Y812* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2
- BUB1B | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CSNK1G2 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.088); called by muse, mutect2
- IGHJ6 | c.47T>A p.V16D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | PolyPhen probably damaging (0.974); called by muse, varscan2
- IGHV2-70D | c.96A>T p.K32N | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- JAK3 | c.309C>G p.R103= | Splice Region (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- MDN1 | c.12851A>G p.Q4284R | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- MSI2 | c.252T>A p.H84Q | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2
- OTOGL | c.1034G>T p.C345F (on ENST00000547103; = p.C336F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLIN4 | c.3240_3243del p.P1081Rfs*6 (on ENST00000301286; = p.P1096Rfs*6 on NM_001367868.2) | Frame Shift Del (DEL) | VAF 52/184 reads (28%) | called by mutect2, pindel, varscan2
- PPL | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PRDM16 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PRKCB | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); called by muse, mutect2
- RLN2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 152/620 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SFT2D2 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SSB | c.1138_1138+1del p.X380_splice | Splice Site (DEL) | VAF 39/105 reads (37%) | called by mutect2, pindel, varscan2
- TNXB | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UTP20 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- AFF2 | c.2922C>T p.D974= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as rs1557288765, COSV53992223; called by muse, mutect2
- CYP27A1 | c.1515G>A p.T505= | Silent (SNP) | VAF 88/167 reads (53%) | catalogued as rs886656814; called by muse, mutect2, varscan2
- ETV3L | c.321G>A p.L107= | Silent (SNP) | VAF 68/152 reads (45%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.177T>C p.R59= | Silent (SNP) | VAF 30/238 reads (13%) | catalogued as rs1180874362; called by muse, varscan2
- IGKV4-1 | c.255T>C p.P85= | Silent (SNP) | VAF 31/31 reads (100%) | catalogued as rs1471751160; called by muse, mutect2, varscan2
- IGLV4-60 | c.276T>C p.S92= | Silent (SNP) | VAF 74/165 reads (45%) | called by muse, varscan2
- ITPRIPL2 | c.723C>T p.R241= | Silent (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- MYOCD | c.2373C>T p.G791= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- SLC12A9 | c.612G>A p.L204= | Silent (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
- SNX29 | c.393C>T p.Y131= | Silent (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- SRPRA | c.147T>C p.H49= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as rs1307715759; called by muse, mutect2, varscan2
- SWAP70 | c.1689T>C p.P563= | Silent (SNP) | VAF 56/311 reads (18%) | called by muse, mutect2, varscan2
- TRABD | c.927C>T p.S309= | Silent (SNP) | VAF 46/129 reads (36%) | called by muse, mutect2, varscan2
- ABCG5 | c.266-90C>T | Intron (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- BANP | c.1345-513G>T | Intron (SNP) | VAF 59/134 reads (44%) | catalogued as COSV53743776; called by muse, mutect2, varscan2
- BBS7 | c.*173A>C | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- BMP6 | c.*802_*816del | 3'UTR (DEL) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- BTF3L4 | c.*2267G>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- C1orf216 | c.*887G>C | 3'UTR (SNP) | VAF 62/183 reads (34%) | called by muse, mutect2, varscan2
- CASP10 | c.1416-8800A>C | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- CNTLN | c.1146+393G>C | Intron (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- CPLANE2 | chr1:16228737 C>T | 3'Flank (SNP) | VAF 49/95 reads (52%) | called by muse, mutect2, varscan2
- CRYBG1 | c.*862G>T | 3'UTR (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- ENPEP | c.*2971A>G | 3'UTR (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- FBXO21 | chr12:117144792 C>T | 3'Flank (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.-36G>T | 5'UTR (SNP) | VAF 9/37 reads (24%) | called by mutect2, varscan2
- KCNJ5 | chr11:128918506 C>A | 3'Flank (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- KRT18P20 | n.701T>C | RNA (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- LYRM2 | c.*3380A>T | 3'UTR (SNP) | VAF 27/31 reads (87%) | called by muse, mutect2, varscan2
- MKRN3 | c.*636T>A | 3'UTR (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- MMP11 | chr22:23768289 G>A | 5'Flank (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- NDE1 | c.*1736C>T | 3'UTR (SNP) | VAF 70/130 reads (54%) | called by muse, mutect2, varscan2
- NLRP3 | c.-637T>C | 5'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- PRELID1P6 | n.70C>T | RNA (SNP) | VAF 14/46 reads (30%) | catalogued as rs990227260; called by muse, mutect2, varscan2
- RHPN2P1 | n.1434C>T | RNA (SNP) | VAF 13/151 reads (9%) | called by muse, mutect2
- SH3BP5L | c.*44G>T | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- SORD | c.*402C>T | 3'UTR (SNP) | VAF 66/308 reads (21%) | called by muse, mutect2
- TIGIT | c.*1945A>T | 3'UTR (SNP) | VAF 30/116 reads (26%) | called by muse, mutect2, varscan2
- TIMM23 | c.-73T>C | 5'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- TNRC18 | chr7:5428192 G>A | 5'Flank (SNP) | VAF 111/181 reads (61%) | catalogued as rs962905867; called by muse, mutect2, varscan2
- TRHDE | c.*2341T>G | 3'UTR (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- TRIM11 | c.859+73G>A | Intron (SNP) | VAF 45/102 reads (44%) | catalogued as rs756695564, COSV99488153; called by muse, mutect2, varscan2
- TTYH2 | c.*251A>G | 3'UTR (SNP) | VAF 61/115 reads (53%) | called by muse, mutect2, varscan2
- UBXN7 | c.*1997T>G | 3'UTR (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- UQCC1 | c.573+1568G>A | Intron (SNP) | VAF 9/106 reads (8%) | catalogued as rs759757168; called by muse, mutect2
- ZNF280D | chr15:56734071 G>A | 5'Flank (SNP) | VAF 254/556 reads (46%) | catalogued as rs916944928; called by muse, mutect2, varscan2
- ZNF383 | c.136+115A>G | Intron (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- ZNF660 | c.*1432C>G | 3'UTR (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
